Gene-level copy-number profile of tumor specimen MP2PRT-PAUPZW-TMP1-A from MP2PRT case MP2PRT-PAUPZW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.0 years (1,100 days).
Specimen MP2PRT-PAUPZW-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f65c193c-6bf8-4be3-992f-25df0a793f36.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAUPZW-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/88912756-698a-432d-9d8a-5c5c19e6bfe3

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 2: 734; copy number 3: 28; copy number 4: 40,381; copy number 5: 104; copy number 6: 15,655; copy number 7: 74; copy number 8: 1,722; copy number 9: 192.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,170,775–89,196,829, 5 genes (within-gene range 0–2): IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26.
- chr9:42,636,788–42,714,539, 3 genes: BX088651.3, FGF7P4, BX664718.1.
- chr9:61,581,813–61,642,494, 3 genes: AL935212.3, FAM242D, Y_RNA.
- chr14:22,438,547–22,450,139, 4 genes (within-gene range 0–6): TRDD1, TRDD2, TRDD3, TRDJ1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 192 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:72,558,744–77,995,171, 177 genes, copy number 9 (broad region; genes not listed).
- chr9:64,462,819–64,889,063, 15 genes, copy number 9: CR769776.2, CYP4F25P, CR769776.1, CNN2P3, GXYLT1P6, AL773524.1, AQP7P2, AL445665.1, BMS1P11, AL359955.2, IGKV1OR-2, BNIP3P4, AL359955.1, AC125634.1, RNU6-1293P.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
